Surgical pathology report (de-identified scan), TCGA case TCGA-XE-A9SE, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-A9SE-01A (Primary Tumor).

[page 1 of 2]
Ord #=
SURGICAL PATHOL
Modifiers:

RESULTED

Collect D/T=

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Right testicle with spermatic cord

Clinical History
Right testicular mass

ICD-3
Seminoma NOS 9061/3
Site (R) Testis NOS C62.9
JTS 3/26/14

Gross Description

Received in formalin and consists of right testicle with spermatic cord: The specimen measures 4.5 x 5 x 4.5 cm overall and weighing 106 gms. The testis measures 7.5 x 5 x 4.5 cm. The spermatic cord measures 7 x 2 x 0.5 cm. Sectioning the specimen reveals multiple, white tan fleshy nodules with necrosis and measuring from a few millimeters to up to 1.2 cm in greatest dimension. The capsule of the testis appears intact. A representative sections as follows:

1. Surgical margin of spermatic cord
2. Cross section of the mid portion of the spermatic cord
3. Cross section of the spermatic cord close to the testis
- 4-10 Representative sections of testis

Date of Dictation:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis
Specimen Type: Orchiectomy
-Laterality: Right
-Tumor Size: 7.5 cm

[page 2 of 2]
SURGICAL PATHOL

(Continued)

Acct#:

- Histologic Type: Seminoma, classic type.
- Intratubular germ cell neoplasia is not identified (entire testis tissue replaced by tumor).
- Tumor is limited to the testis. Tumor does not involve rete testis, epididymis, spermatic cord, tunica vaginalis, or scrotal wall.
- Margin: Spermatic cord margin is negative.
- Remaining testicular tissue shows fibrosis and chronic inflammation.
- No residual normal testicular tissue identified.

Pathologic Tumor Stage: pT1NXMX (Stage IA)

Attending Pathologist:

***Electronically Signed Out By

Source: NCI Genomic Data Commons file a2c95a2c-3d61-4f68-99b4-3f1af602d695 (TCGA-XE-A9SE.BE98A5BF-24D3-42AE-A666-94E52DFB1101.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).